Somatic mutation profile of tumor specimen TCGA-FJ-A3ZF-01A (aliquot TCGA-FJ-A3ZF-01A-11D-A23M-08) from TCGA case TCGA-FJ-A3ZF, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Papillary transitional cell carcinoma; Tissue or organ of origin: Bladder, NOS; AJCC pathologic stage: Stage III; Tumor grade: High Grade; Age at diagnosis: 73.4 years (26,825 days).
Specimen TCGA-FJ-A3ZF-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4df6df35-4ee7-4e3f-9b35-7b3a446ecadf.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-FJ-A3ZF-10A (Blood Derived Normal), aliquot TCGA-FJ-A3ZF-10A-01D-A23K-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e803b874-15e8-43c5-89b6-df5c22b0e5dd

The open-access MAF lists 278 somatic variants for this specimen: 201 protein-altering or splice-affecting, 64 silent, 13 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 172, Silent 64, Nonsense Mutation 18, 5'Flank 9, Splice Region 4, Splice Site 3, Intron 2, Frame Shift Del 2, Frame Shift Ins 1, 3'UTR 1, In Frame Del 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ERBB3 | c.310G>T p.V104L | Missense Mutation (SNP) | VAF 99/176 reads (56%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen benign (0.119); catalogued as rs1057519893, COSV57246387, COSV57246465, COSV57253558; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- RXRA | c.1280C>A p.S427Y | Missense Mutation (SNP) | VAF 80/134 reads (60%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1057519958, COSV62683447, COSV62683496, COSV62683653; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.853G>A p.E285K | Missense Mutation (SNP) | VAF 78/80 reads (98%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs112431538, CM123560, CM995136, COSV52661732, COSV52670664, COSV53234441, COSV53650254; ClinVar: drug response / pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- A1CF | c.358G>A p.E120K | Missense Mutation (SNP) | VAF 16/59 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.345); catalogued as COSV50962227; called by muse, mutect2, varscan2
- ABCA6 | c.4762G>C p.E1588Q | Missense Mutation (SNP) | VAF 22/48 reads (46%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV52636694, COSV52644080; called by muse, mutect2, varscan2
- ACAP3 | c.1118G>C p.C373S | Missense Mutation (SNP) | VAF 36/56 reads (64%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as rs146361230; called by muse, mutect2, varscan2
- ACIN1 | c.1906G>C p.E636Q | Missense Mutation (SNP) | VAF 99/228 reads (43%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.968); catalogued as rs540245781, COSV52981500; called by muse, mutect2, varscan2
- ADRB2 | c.709G>C p.E237Q | Missense Mutation (SNP) | VAF 6/107 reads (6%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.471); catalogued as COSV60005711; called by muse, mutect2
- AKAP6 | c.4349C>T p.T1450I | Missense Mutation (SNP) | VAF 30/60 reads (50%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.36); catalogued as rs367910480; called by muse, mutect2, varscan2
- ANK3 | c.4435G>A p.E1479K | Missense Mutation (SNP) | VAF 31/41 reads (76%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.339); catalogued as COSV55078833; called by muse, mutect2, varscan2
- ANKHD1-EIF4EBP3 | c.3887T>C p.L1296S | Missense Mutation (SNP) | VAF 28/55 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51856980; called by muse, mutect2, varscan2
- AQP2 | c.224G>T p.C75F | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV52231804; called by muse, mutect2, varscan2
- ARAP1 | c.787G>T p.V263L (on ENST00000393609 / NM_001040118.2; = p.V18L on NM_015242.4) | Missense Mutation (SNP) | VAF 158/252 reads (63%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as COSV61994542; called by muse, mutect2, varscan2
- ARHGEF6 | c.1747C>T p.P583S | Missense Mutation (SNP) | VAF 10/182 reads (5%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.839); catalogued as COSV51695499; called by muse, mutect2
- ARID1A | c.6032T>G p.L2011R | Missense Mutation (SNP) | VAF 37/115 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61387729; called by muse, mutect2, varscan2
- ATAD5 | c.149G>C p.R50T | Missense Mutation (SNP) | VAF 33/125 reads (26%) | SIFT tolerated (0.33); PolyPhen benign (0.012); catalogued as rs1567675700, COSV58978257; called by muse, mutect2
- ATP10A | c.2260C>T p.R754W | Missense Mutation (SNP) | VAF 31/98 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs755143094, COSV63523111; called by muse, mutect2, varscan2
- ATP10D | c.1229A>G p.Y410C | Missense Mutation (SNP) | VAF 15/31 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV56712555; called by muse, mutect2, varscan2
- ATP10D | c.3240G>A p.Q1080= | Splice Region (SNP) | VAF 31/65 reads (48%) | catalogued as COSV56712472; called by muse, mutect2, varscan2
- ATP1A2 | c.612C>G p.I204M | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.848); catalogued as COSV63405701; called by muse, mutect2, varscan2
- BACH2 | c.2056G>C p.E686Q | Missense Mutation (SNP) | VAF 44/79 reads (56%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.642); catalogued as COSV57606846; called by muse, mutect2, varscan2
- BBX | c.287C>T p.S96F | Missense Mutation (SNP) | VAF 117/189 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57893561; called by muse, mutect2, varscan2
- BMPR2 | c.2294C>T p.S765L | Missense Mutation (SNP) | VAF 24/109 reads (22%) | SIFT tolerated (0.15); PolyPhen benign (0.038); catalogued as COSV101001484, COSV65813147; called by muse, mutect2, varscan2
- C12orf56 | c.1210G>A p.D404N (on ENST00000543942 / NM_001170633.2; = p.D244N on NM_001099676.3) | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT tolerated (0.09); PolyPhen benign (0.313); catalogued as rs1489845765, COSV61489735; called by muse, mutect2, varscan2
- C12orf66 | c.796C>T p.L266F | Missense Mutation (SNP) | VAF 48/161 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as COSV61324537; called by muse, mutect2, varscan2
- C7orf33 | c.191C>A p.T64K | Missense Mutation (SNP) | VAF 106/134 reads (79%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.678); catalogued as COSV61023626, COSV61023860; called by muse, mutect2, varscan2
- CASP1 | c.1020G>A p.W340* (on ENST00000436863 / NM_033292.4; = p.W319* on NM_001223.5 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 48/79 reads (61%) | catalogued as rs1304854503; called by muse, mutect2, varscan2
- CCR5 | c.902G>A p.G301E | Missense Mutation (SNP) | VAF 306/609 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as CM016305, COSV52752840; called by muse, mutect2, varscan2
- CD5L | c.797G>C p.G266A | Missense Mutation (SNP) | VAF 49/195 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63822964; called by muse, mutect2, varscan2
- CDH8 | c.1649A>G p.N550S | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.838); catalogued as COSV54895935; called by muse, mutect2
- CENPE | c.6946G>C p.E2316Q | Missense Mutation (SNP) | VAF 41/81 reads (51%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.879); catalogued as COSV54388892; called by muse, mutect2, varscan2
- CHST15 | c.923A>C p.Y308S | Missense Mutation (SNP) | VAF 42/74 reads (57%) | SIFT tolerated (0.07); PolyPhen benign (0.007); catalogued as rs201649749, COSV60565473; called by muse, mutect2, varscan2
- CIT | c.1730C>T p.S577L | Missense Mutation (SNP) | VAF 126/187 reads (67%) | SIFT tolerated (0.11); PolyPhen benign (0.039); catalogued as COSV55881296; called by muse, mutect2, varscan2
- CLK4 | c.115G>A p.E39K | Missense Mutation (SNP) | VAF 58/115 reads (50%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.108); catalogued as COSV60318126, COSV60320843; called by muse, mutect2, varscan2
- CNTNAP5 | c.598A>T p.T200S | Missense Mutation (SNP) | VAF 23/106 reads (22%) | SIFT tolerated (0.37); PolyPhen benign (0.014); catalogued as COSV70496450; called by muse, mutect2, varscan2
- COIL | c.1255C>T p.R419* | Nonsense Mutation (SNP) | VAF 55/172 reads (32%) | catalogued as rs750972140; called by muse, mutect2, varscan2
- COL5A1 | c.3733G>A p.V1245M | Missense Mutation (SNP) | VAF 48/85 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); catalogued as rs1435045393, COSV65673930; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COPS3 | c.24C>A p.F8L | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT tolerated (0.09); PolyPhen benign (0.007); catalogued as COSV99253829; called by muse, mutect2
- DCST2 | c.1894C>T p.R632C | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.548); catalogued as rs764181998, COSV55054260; called by muse, mutect2, varscan2
- DCST2 | c.1601C>T p.S534F | Missense Mutation (SNP) | VAF 31/165 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.005); catalogued as rs1197749238, COSV55054268; called by muse, mutect2, varscan2
- DENND5B | c.2489G>A p.R830K | Missense Mutation (SNP) | VAF 4/31 reads (13%) | SIFT tolerated (0.14); PolyPhen benign (0.223); catalogued as rs1237808996; called by muse, mutect2
- DHRSX | c.310G>A p.A104T | Missense Mutation (SNP) | VAF 196/357 reads (55%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.615); catalogued as COSV58138331; called by muse, mutect2, varscan2
- DMRT2 | c.812C>G p.P271R | Missense Mutation (SNP) | VAF 23/186 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs776953319, COSV52403469; called by muse, mutect2, varscan2
- DNHD1 | c.12790C>G p.L4264V | Missense Mutation (SNP) | VAF 18/33 reads (55%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.448); catalogued as COSV54442786; called by muse, mutect2, varscan2
- DNPEP | c.336G>A p.V112= | Splice Region (SNP) | VAF 25/110 reads (23%) | catalogued as COSV56111831; called by muse, mutect2, varscan2
- DOCK3 | c.1517G>A p.R506H | Missense Mutation (SNP) | VAF 87/197 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56517905; called by muse, mutect2, varscan2
- DSPP | c.461C>G p.T154S | Missense Mutation (SNP) | VAF 22/53 reads (42%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0.007); catalogued as rs1422531293, COSV56815715; called by muse, mutect2, varscan2
- EFEMP1 | c.489C>G p.Y163* | Nonsense Mutation (SNP) | VAF 62/311 reads (20%) | catalogued as COSV100816704; called by muse, mutect2, varscan2
- ELF3 | c.1010A>G p.Y337C | Missense Mutation (SNP) | VAF 106/108 reads (98%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62839500; called by muse, mutect2, varscan2
- EP300 | c.3439G>T p.E1147* | Nonsense Mutation (SNP) | VAF 48/104 reads (46%) | catalogued as COSV54332615, COSV99609546; called by muse, mutect2, varscan2
- ETFDH | c.1439G>A p.G480E | Missense Mutation (SNP) | VAF 23/55 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56989102; called by muse, mutect2, varscan2
- FAM126A | c.737_743+3del p.X246_splice | Splice Site (DEL) | VAF 30/66 reads (45%) | catalogued as COSV69472440; called by mutect2, pindel, varscan2
- FAM209A | c.509C>G p.S170C | Missense Mutation (SNP) | VAF 28/80 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.601); catalogued as COSV54768913; called by muse, mutect2, varscan2
- FANK1 | c.991G>C p.E331Q | Missense Mutation (SNP) | VAF 19/74 reads (26%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.994); catalogued as COSV64136363, COSV64138048; called by muse, mutect2, varscan2
- FBLN2 | c.2033C>T p.P678L | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT tolerated (0.12); PolyPhen benign (0.194); catalogued as rs749311967; called by muse, mutect2, varscan2
- FGFR3 | c.916G>A p.V306I | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.968); catalogued as rs774047997, COSV53417648; ClinVar: uncertain significance; called by muse, mutect2
- FLNB | c.2200-1G>A p.X734_splice | Splice Site (SNP) | VAF 81/177 reads (46%) | catalogued as COSV55893732; called by muse, mutect2, varscan2
- FLNC | c.1857C>A p.D619E | Missense Mutation (SNP) | VAF 17/223 reads (8%) | SIFT tolerated (0.41); PolyPhen benign (0.018); catalogued as rs771469976, COSV57963744; called by muse, mutect2
- GAB3 | c.235G>C p.E79Q | Missense Mutation (SNP) | VAF 95/161 reads (59%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.999); catalogued as COSV65818942, COSV65820626; called by muse, mutect2, varscan2
- GAL3ST4 | c.452_454del p.D151_S152delinsG | In Frame Del (DEL) | VAF 32/91 reads (35%) | catalogued as COSV57588071; called by mutect2, pindel, varscan2
- GLRA3 | c.35C>T p.S12L | Missense Mutation (SNP) | VAF 21/53 reads (40%) | SIFT tolerated, low confidence (0.24); PolyPhen possibly damaging (0.706); catalogued as rs997896587, COSV56862714; called by muse, mutect2, varscan2
- GMDS | c.1069G>A p.E357K | Missense Mutation (SNP) | VAF 19/36 reads (53%) | SIFT deleterious, low confidence (0.05); PolyPhen possibly damaging (0.583); catalogued as COSV66418018; called by muse, mutect2, varscan2
- GPI | c.893C>T p.S298L | Missense Mutation (SNP) | VAF 80/181 reads (44%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.075); catalogued as rs763375030, COSV62894805; called by muse, mutect2, varscan2
- GSX2 | c.859G>A p.E287K | Missense Mutation (SNP) | VAF 30/54 reads (56%) | SIFT deleterious (0); PolyPhen benign (0.204); catalogued as COSV58843455; called by muse, mutect2
- HCFC1 | c.109C>T p.R37C | Missense Mutation (SNP) | VAF 17/21 reads (81%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV60074789, COSV60076091; called by muse, mutect2, varscan2
- HECW1 | c.1996G>A p.G666R | Missense Mutation (SNP) | VAF 13/98 reads (13%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.039); catalogued as rs752558345, COSV67822233, COSV67824868; called by muse, mutect2, varscan2
- HERC2 | c.12710T>C p.V4237A | Missense Mutation (SNP) | VAF 88/303 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55346974; called by muse, mutect2, varscan2
- HSD3B1 | c.784C>T p.H262Y | Missense Mutation (SNP) | VAF 142/210 reads (68%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.791); catalogued as rs766074041, COSV52492019; called by muse, mutect2, varscan2
- ICAM5 | c.2019C>A p.C673* | Nonsense Mutation (SNP) | VAF 63/97 reads (65%) | catalogued as COSV99703468; called by muse, mutect2, varscan2
- IGF2 | c.358C>T p.R120C (on ENST00000434045 / NM_001127598.3; = p.R64C on NM_000612.6) | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs762200142, COSV56101377; called by muse, mutect2, varscan2
- IL18RAP | c.1200G>C p.Q400H | Missense Mutation (SNP) | VAF 240/438 reads (55%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as COSV51828838; called by muse, mutect2, varscan2
- IL1RAP | c.1492G>C p.V498L | Missense Mutation (SNP) | VAF 63/205 reads (31%) | SIFT tolerated (0.54); PolyPhen benign (0.026); catalogued as COSV50769026, COSV50769670; called by muse, mutect2, varscan2
- IMPG2 | c.2576A>G p.N859S | Missense Mutation (SNP) | VAF 53/149 reads (36%) | SIFT tolerated (0.24); PolyPhen benign (0.001); catalogued as COSV51984644; called by muse, mutect2, varscan2
- INTS1 | c.3142C>G p.L1048V | Missense Mutation (SNP) | VAF 14/111 reads (13%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as rs948025536, COSV67179482; called by muse, mutect2, varscan2
- INTS13 | c.1234G>A p.D412N | Missense Mutation (SNP) | VAF 34/64 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV53905163; called by muse, mutect2, varscan2
- IRF9 | c.80G>A p.G27E | Missense Mutation (SNP) | VAF 64/143 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60703920; called by muse, mutect2, varscan2
- ITCH | c.1928G>A p.R643K (on ENST00000262650 / NM_001257137.3; = p.R602K on NM_031483.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 40/72 reads (56%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.888); catalogued as COSV52936553; called by muse, mutect2, varscan2
- ITGA8 | c.920C>T p.T307M | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.98); catalogued as rs750689734, COSV65228257; called by muse, mutect2, varscan2
- JMJD1C | c.5083C>T p.P1695S | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV59517645; called by muse, mutect2, varscan2
- KAT14 | c.945G>C p.L315F | Missense Mutation (SNP) | VAF 105/345 reads (30%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.541); catalogued as COSV66609155; called by muse, mutect2, varscan2
- KCNH7 | c.2291C>A p.T764N | Missense Mutation (SNP) | VAF 141/255 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as COSV59811451; called by muse, mutect2, varscan2
- KDM5D | c.1920G>C p.K640N | Missense Mutation (SNP) | VAF 52/55 reads (95%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.756); catalogued as COSV58737208; called by muse, mutect2, varscan2
- KIAA1522 | c.1369G>C p.D457H (on ENST00000373480 / NM_001198972.2; = p.D516H on NM_020888.3) | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.895); catalogued as COSV53867354; called by muse, mutect2, varscan2
- KIF16B | c.2705T>G p.L902R | Missense Mutation (SNP) | VAF 85/159 reads (53%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.549); catalogued as COSV61713287; called by muse, mutect2, varscan2
- KLK15 | c.406G>A p.E136K | Missense Mutation (SNP) | VAF 18/121 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.388); catalogued as rs749169024, COSV100032786, COSV56828407; called by muse, mutect2, varscan2
- KLK15 | c.218G>A p.G73E | Missense Mutation (SNP) | VAF 22/155 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56827325; called by muse, mutect2, varscan2
- KNL1 | c.6088G>A p.E2030K (on ENST00000346991 / NM_170589.5; = p.E2004K on NM_144508.5) | Missense Mutation (SNP) | VAF 22/49 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.747); catalogued as COSV61159791; called by muse, mutect2, varscan2
- KRT82 | c.1453G>A p.E485K | Missense Mutation (SNP) | VAF 33/113 reads (29%) | SIFT tolerated (0.64); PolyPhen benign (0.041); catalogued as rs140708995; called by muse, mutect2, varscan2
- KRT83 | c.448G>C p.E150Q | Missense Mutation (SNP) | VAF 115/180 reads (64%) | SIFT tolerated (0.13); PolyPhen benign (0.015); catalogued as COSV53342355; called by muse, mutect2, varscan2
- LACTB | c.1369G>A p.E457K | Missense Mutation (SNP) | VAF 31/104 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.048); catalogued as COSV56056873; called by muse, mutect2, varscan2
- LAMP1 | c.947C>T p.P316L | Missense Mutation (SNP) | VAF 99/153 reads (65%) | SIFT deleterious (0.03); PolyPhen benign (0.091); catalogued as COSV58151915; called by muse, mutect2, varscan2
- LRFN2 | c.296_299del p.L99Rfs*32 | Frame Shift Del (DEL) | VAF 14/50 reads (28%) | catalogued as COSV57833758; called by mutect2, pindel, varscan2
- LRP2 | c.6568G>C p.D2190H | Missense Mutation (SNP) | VAF 108/206 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55571125; called by muse, mutect2, varscan2
- MAGOH | c.245G>A p.R82Q | Missense Mutation (SNP) | VAF 93/183 reads (51%) | SIFT deleterious (0.04); PolyPhen benign (0.21); catalogued as rs762974089, COSV65161416; called by muse, mutect2, varscan2
- MAP1A | c.1453A>C p.K485Q | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs2584715, COSV55812061; called by muse, mutect2, varscan2
- MAP3K6 | c.3520G>C p.D1174H | Missense Mutation (SNP) | VAF 9/69 reads (13%) | SIFT tolerated (0.11); PolyPhen benign (0.101); catalogued as COSV58874184; called by muse, mutect2, varscan2
- MAP4K5 | c.1425A>C p.K475N | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.877); catalogued as COSV50160421; called by muse, mutect2, varscan2
- MOSPD2 | c.1001A>C p.E334A | Missense Mutation (SNP) | VAF 34/36 reads (94%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV66860779; called by muse, varscan2
- MPP2 | c.1358C>T p.T453I (on ENST00000461854 / NM_001278372.2; = p.T429I on NM_005374.5) | Missense Mutation (SNP) | VAF 38/121 reads (31%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.85); catalogued as COSV52239793; called by muse, mutect2, varscan2
- MSR1 | c.1104C>A p.S368R | Missense Mutation (SNP) | VAF 50/60 reads (83%) | SIFT tolerated (0.21); PolyPhen benign (0.029); catalogued as COSV50529985; called by muse, mutect2, varscan2
- MYO3B | c.2134G>T p.A712S | Missense Mutation (SNP) | VAF 23/137 reads (17%) | SIFT tolerated (0.78); PolyPhen benign (0.038); catalogued as COSV58715431; called by muse, mutect2, varscan2
- NEB | c.10953G>C p.K3651N | Missense Mutation (SNP) | VAF 40/65 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV51455571; called by muse, mutect2, varscan2
- NFATC1 | c.818G>T p.R273L | Missense Mutation (SNP) | VAF 14/57 reads (25%) | SIFT tolerated (0.07); PolyPhen benign (0.44); catalogued as COSV53708294; called by muse, mutect2, varscan2
- NLRP5 | c.1366C>T p.R456C | Missense Mutation (SNP) | VAF 26/68 reads (38%) | SIFT tolerated (0.12); PolyPhen benign (0.071); catalogued as rs780213439, COSV66764769; called by muse, mutect2, varscan2
- NRXN1 | c.2376C>A p.S792R | Missense Mutation (SNP) | VAF 8/85 reads (9%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.845); catalogued as COSV58445057; called by muse, mutect2
- NTF4 | c.286G>A p.V96M | Missense Mutation (SNP) | VAF 40/77 reads (52%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.999); catalogued as rs773531060, COSV56825369; called by muse, mutect2, varscan2
- OPN1SW | c.217C>G p.L73V | Missense Mutation (SNP) | VAF 182/225 reads (81%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50823218; called by muse, mutect2, varscan2
- OSGEP | c.785G>T p.G262V | Missense Mutation (SNP) | VAF 109/173 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52833692; called by muse, mutect2, varscan2
- PCDHB5 | c.1657G>A p.A553T | Missense Mutation (SNP) | VAF 27/91 reads (30%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.01); catalogued as rs782073750, COSV50653048; called by muse, mutect2, varscan2
- PCNX2 | c.5707G>C p.G1903R | Missense Mutation (SNP) | VAF 25/73 reads (34%) | SIFT tolerated (0.55); PolyPhen benign (0.023); catalogued as COSV50787414, COSV50871484; called by muse, mutect2, varscan2
- PCSK6 | c.996G>A p.K332= | Splice Region (SNP) | VAF 61/222 reads (27%) | catalogued as COSV59344201; called by muse, mutect2, varscan2
- PDCD11 | c.4921G>A p.V1641M | Missense Mutation (SNP) | VAF 83/130 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs140495953; called by muse, mutect2, varscan2
- PDE3A | c.1771C>A p.P591T | Missense Mutation (SNP) | VAF 18/47 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.062); catalogued as COSV62981726; called by muse, mutect2, varscan2
- PDE5A | c.751T>G p.F251V | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53352312; called by muse, mutect2, varscan2
- PHLDB2 | c.2485G>C p.E829Q (on ENST00000393925 / NM_001134439.2; = p.E786Q on NM_145753.2) | Missense Mutation (SNP) | VAF 29/51 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV67315484; called by muse, mutect2, varscan2
- PIK3C2A | c.4708C>T p.R1570* | Nonsense Mutation (SNP) | VAF 45/79 reads (57%) | catalogued as rs1479089848; called by muse, mutect2, varscan2
- PKHD1 | c.5348C>T p.S1783F | Missense Mutation (SNP) | VAF 40/81 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.823); catalogued as COSV61892407; called by muse, mutect2, varscan2
- PLA1A | c.1072G>A p.E358K | Missense Mutation (SNP) | VAF 54/82 reads (66%) | SIFT tolerated (0.15); PolyPhen benign (0.001); catalogued as rs921530538, COSV56333607; called by muse, mutect2, varscan2
- PLEC | c.11514G>C p.R3838S (on ENST00000322810 / NM_201380.4; = p.R3728S on NM_000445.5) | Missense Mutation (SNP) | VAF 24/116 reads (21%) | SIFT tolerated (0.48); PolyPhen benign (0.043); catalogued as COSV59689464; called by muse, mutect2, varscan2
- PLVAP | c.350G>A p.R117H | Missense Mutation (SNP) | VAF 22/63 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.928); catalogued as rs199706929, COSV53085595; called by muse, mutect2, varscan2
- POLD1 | c.532G>T p.G178W | Missense Mutation (SNP) | VAF 53/111 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); catalogued as rs140707092, COSV70957044; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- POLD1 | c.2450G>A p.R817Q | Missense Mutation (SNP) | VAF 49/106 reads (46%) | SIFT deleterious (0.02); PolyPhen benign (0.037); catalogued as rs142017093, COSV54532459; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- POLI | c.484G>C p.E162Q | Missense Mutation (SNP) | VAF 15/33 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.62); catalogued as COSV54191572; called by muse, mutect2, varscan2
- PPRC1 | c.4244C>T p.S1415L | Missense Mutation (SNP) | VAF 80/117 reads (68%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.014); catalogued as COSV53388164; called by muse, mutect2, varscan2
- PROSER3 | c.721G>A p.E241K | Missense Mutation (SNP) | VAF 17/255 reads (7%) | SIFT tolerated (0.88); PolyPhen benign (0.031); catalogued as rs370565442; called by muse, mutect2
- PRPH | c.1097G>C p.R366P | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.793); catalogued as COSV57679641; called by muse, mutect2, varscan2
- PSMA8 | c.234G>C p.L78F | Missense Mutation (SNP) | VAF 81/110 reads (74%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.028); catalogued as COSV57603797, COSV57604844; called by muse, mutect2, varscan2
- PSMB8 | c.459G>T p.K153N (on ENST00000374882 / NM_148919.4; = p.K149N on NM_004159.5) | Missense Mutation (SNP) | VAF 51/102 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62755628; called by muse, mutect2, varscan2
- PTHLH | c.229G>C p.E77Q | Missense Mutation (SNP) | VAF 38/370 reads (10%) | SIFT tolerated (0.35); PolyPhen probably damaging (0.975); catalogued as COSV52369349; called by muse, mutect2
- RBMXL2 | c.775G>A p.D259N | Missense Mutation (SNP) | VAF 23/73 reads (32%) | SIFT tolerated (0.11); PolyPhen benign (0.381); catalogued as COSV100182224, COSV60981497; called by muse, mutect2, varscan2
- RESF1 | c.5009G>C p.G1670A | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.942); catalogued as COSV57025180; called by muse, mutect2, varscan2
- REST | c.769A>G p.T257A | Missense Mutation (SNP) | VAF 46/86 reads (53%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.993); catalogued as COSV58362519; called by muse, mutect2, varscan2
- RHOB | c.139G>A p.E47K | Missense Mutation (SNP) | VAF 29/142 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.199); catalogued as COSV55355615, COSV55357131; called by muse, mutect2, varscan2
- RNF128 | c.1162C>G p.L388V (on ENST00000255499 / NM_194463.2; = p.L362V on NM_024539.3) | Missense Mutation (SNP) | VAF 50/108 reads (46%) | SIFT tolerated (0.11); PolyPhen benign (0.095); catalogued as COSV55254107; called by muse, mutect2, varscan2
- ROBO2 | c.2527G>C p.E843Q | Missense Mutation (SNP) | VAF 46/105 reads (44%) | SIFT tolerated (0.1); PolyPhen benign (0.276); catalogued as COSV59934718; called by muse, mutect2, varscan2
- RPL22 | c.44dup p.K16Efs*9 | Frame Shift Ins (INS) | VAF 34/52 reads (65%) | catalogued as rs759765382; called by mutect2, varscan2
- RTN4IP1 | c.718G>T p.A240S | Missense Mutation (SNP) | VAF 56/105 reads (53%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.993); catalogued as COSV64806354; called by muse, mutect2, varscan2
- RYR1 | c.1474C>T p.R492C | Missense Mutation (SNP) | VAF 69/184 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs199826952, COSV62109089; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SACS | c.1560G>C p.K520N | Missense Mutation (SNP) | VAF 65/181 reads (36%) | SIFT tolerated (0.06); PolyPhen benign (0.01); catalogued as rs766788204, COSV66546174; called by muse, mutect2, varscan2
- SAMD3 | c.116A>G p.N39S | Missense Mutation (SNP) | VAF 68/130 reads (52%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.997); catalogued as rs200818614, COSV60775050; called by muse, mutect2, varscan2
- SCN1A | c.4812G>A p.W1604* (on ENST00000303395 / NM_001202435.3; = p.W1593* on NM_006920.6 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 14/49 reads (29%) | catalogued as rs1553520955; called by muse, mutect2, varscan2
- SEMA3E | c.877G>A p.V293I | Missense Mutation (SNP) | VAF 69/160 reads (43%) | SIFT tolerated (0.4); PolyPhen benign (0.08); catalogued as rs755474658, COSV57082035, COSV57105225; called by muse, mutect2, varscan2
- SEMA6B | c.1180G>A p.D394N | Missense Mutation (SNP) | VAF 42/73 reads (58%) | SIFT deleterious (0); PolyPhen benign (0.416); catalogued as rs1425583221, COSV56705808; called by muse, mutect2, varscan2
- SLC6A8 | c.1332G>T p.E444D | Missense Mutation (SNP) | VAF 106/111 reads (95%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); catalogued as COSV53473348; called by muse, mutect2, varscan2
- SMARCA2 | c.3139C>T p.R1047W | Missense Mutation (SNP) | VAF 129/235 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV61806264; called by muse, mutect2, varscan2
- SMARCA4 | c.4308G>C p.E1436D | Missense Mutation (SNP) | VAF 24/37 reads (65%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as COSV60807457; called by muse, mutect2, varscan2
- SMOC2 | c.1292G>A p.R431K (on ENST00000356284 / NM_001166412.2; = p.R442K on NM_022138.3) | Missense Mutation (SNP) | VAF 11/93 reads (12%) | SIFT tolerated, low confidence (0.5); PolyPhen benign (0); catalogued as rs765197089, COSV100634839, COSV100635589, COSV62443760; called by muse, mutect2, varscan2
- SOGA3 | c.2510G>C p.S837T | Missense Mutation (SNP) | VAF 62/237 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.416); catalogued as COSV64107760, COSV64108408; called by muse, mutect2, varscan2
- SPA17 | c.239C>A p.P80H | Missense Mutation (SNP) | VAF 53/88 reads (60%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.527); catalogued as COSV57033068; called by muse, mutect2, varscan2
- SRPRA | c.1171G>C p.E391Q | Missense Mutation (SNP) | VAF 50/85 reads (59%) | SIFT tolerated (0.09); PolyPhen benign (0.271); catalogued as COSV55008783; called by muse, mutect2, varscan2
- SSU72 | c.460C>T p.L154F | Missense Mutation (SNP) | VAF 38/143 reads (27%) | SIFT tolerated (0.1); PolyPhen benign (0.068); catalogued as COSV52218911; called by muse, mutect2, varscan2
- STAMBP | c.673G>T p.V225L | Missense Mutation (SNP) | VAF 24/180 reads (13%) | SIFT tolerated (0.73); PolyPhen benign (0.001); catalogued as rs1355731734, COSV59898280; called by muse, mutect2, varscan2
- STIL | c.1072G>A p.E358K | Missense Mutation (SNP) | VAF 28/57 reads (49%) | SIFT tolerated (0.05); PolyPhen benign (0.041); catalogued as COSV54553208; called by muse, mutect2, varscan2
- STON1-GTF2A1L | c.3075A>G p.I1025M | Missense Mutation (SNP) | VAF 25/77 reads (32%) | SIFT tolerated (0.16); PolyPhen benign (0.054); catalogued as COSV59137020; called by muse, mutect2, varscan2
- TAF1L | c.1320C>G p.I440M | Missense Mutation (SNP) | VAF 222/372 reads (60%) | SIFT deleterious (0.02); PolyPhen benign (0.395); catalogued as COSV54268004; called by muse, mutect2, varscan2
- TANK | c.1070C>A p.S357Y | Missense Mutation (SNP) | VAF 60/132 reads (45%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.642); catalogued as rs755618514, COSV52047554; called by muse, mutect2, varscan2
- TBC1D16 | c.1503C>A p.F501L | Missense Mutation (SNP) | VAF 106/261 reads (41%) | SIFT deleterious (0.04); PolyPhen benign (0.03); catalogued as COSV60476595; called by muse, mutect2, varscan2
- TCP11L1 | c.367G>T p.D123Y | Missense Mutation (SNP) | VAF 72/262 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.831); catalogued as COSV57514028; called by muse, mutect2, varscan2
- TMEM132B | c.2395G>A p.G799S | Missense Mutation (SNP) | VAF 32/107 reads (30%) | SIFT tolerated (0.37); PolyPhen benign (0.015); catalogued as COSV54767619; called by muse, mutect2, varscan2
- TNPO1 | c.2243-1G>C p.X748_splice | Splice Site (SNP) | VAF 26/50 reads (52%) | catalogued as COSV61523720; called by muse, mutect2, varscan2
- TRAPPC13 | c.591G>C p.Q197H | Missense Mutation (SNP) | VAF 7/12 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs781238575, COSV51560190; called by muse, mutect2, varscan2
- TRIP11 | c.17G>C p.G6A | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV50974692; called by muse, mutect2
- TTLL3 | c.1027C>G p.L343V | Missense Mutation (SNP) | VAF 69/280 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.046); catalogued as rs1327475235, COSV59615687; called by muse, mutect2, varscan2
- TUBA1C | c.1090C>A p.P364T | Missense Mutation (SNP) | VAF 75/123 reads (61%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.998); catalogued as COSV56511658; called by muse, mutect2, varscan2
- UBASH3A | c.1876G>T p.E626* | Nonsense Mutation (SNP) | VAF 70/247 reads (28%) | catalogued as COSV52315082; called by muse, mutect2, varscan2
- USO1 | c.1737G>C p.E579D | Missense Mutation (SNP) | VAF 39/66 reads (59%) | SIFT tolerated (0.82); PolyPhen benign (0.025); catalogued as COSV53710153; called by muse, mutect2, varscan2
- WAC | c.794C>G p.S265C | Missense Mutation (SNP) | VAF 50/187 reads (27%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.237); catalogued as COSV61569526; called by muse, mutect2, varscan2
- WAC | c.1765G>C p.E589Q | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV100610850, COSV61569535; called by muse, varscan2
- WAC | c.1772A>G p.H591R | Missense Mutation (SNP) | VAF 18/48 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs1326940885, COSV61569539; called by muse, varscan2
- WNT2 | c.187C>T p.R63C | Missense Mutation (SNP) | VAF 36/42 reads (86%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.806); catalogued as rs376068978, COSV55411972; called by muse, mutect2, varscan2
- XPR1 | c.1166T>G p.V389G | Missense Mutation (SNP) | VAF 19/124 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62560109; called by muse, varscan2
- XYLB | c.157C>G p.H53D | Missense Mutation (SNP) | VAF 103/214 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.61); catalogued as COSV52915552, COSV99264321; called by muse, mutect2, varscan2
- ZBTB9 | c.1360C>G p.L454V | Missense Mutation (SNP) | VAF 69/125 reads (55%) | SIFT deleterious (0.02); PolyPhen benign (0.444); catalogued as COSV67702381; called by muse, mutect2, varscan2
- ZCCHC14 | c.162C>T p.I54= (on ENST00000268616; = p.I191= on NM_015144.3) | Splice Region (SNP) | VAF 10/172 reads (6%) | catalogued as COSV51890004; called by muse, mutect2
- ZDBF2 | c.2777C>T p.S926L | Missense Mutation (SNP) | VAF 18/57 reads (32%) | SIFT deleterious (0.05); PolyPhen benign (0.049); catalogued as COSV65629583; called by muse, mutect2, varscan2
- ZFYVE26 | c.7421G>A p.R2474Q | Missense Mutation (SNP) | VAF 18/56 reads (32%) | SIFT tolerated (0.69); PolyPhen benign (0.001); catalogued as rs752814396; called by muse, mutect2
- ZNF217 | c.82C>G p.L28V | Missense Mutation (SNP) | VAF 43/100 reads (43%) | SIFT tolerated (0.62); PolyPhen benign (0.014); catalogued as COSV56601757; called by muse, mutect2, varscan2
- ZNF385D | c.342G>A p.M114I | Missense Mutation (SNP) | VAF 77/157 reads (49%) | SIFT tolerated (0.37); PolyPhen benign (0.003); catalogued as rs1189602032, COSV55749213; called by muse, mutect2, varscan2
- ZNF516 | c.468C>A p.S156R | Missense Mutation (SNP) | VAF 4/9 reads (44%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.708); catalogued as COSV71587577; called by muse, mutect2, varscan2
- ZNF532 | c.2428C>A p.P810T | Missense Mutation (SNP) | VAF 62/156 reads (40%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.517); catalogued as COSV60172296, COSV60175292; called by muse, mutect2, varscan2
- ZNF560 | c.1418C>T p.S473L | Missense Mutation (SNP) | VAF 48/241 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.544); catalogued as rs747835689, COSV56871139; called by muse, mutect2, varscan2
- ZNF614 | c.1420G>A p.E474K | Missense Mutation (SNP) | VAF 29/335 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.095); catalogued as COSV54547434; called by muse, mutect2
- ZNF653 | c.1201G>A p.E401K | Missense Mutation (SNP) | VAF 55/151 reads (36%) | SIFT tolerated (0.24); PolyPhen benign (0.351); catalogued as rs1568393396, COSV53404591; called by muse, mutect2, varscan2
- ZNF662 | c.163C>G p.L55V | Missense Mutation (SNP) | VAF 17/78 reads (22%) | SIFT tolerated (0.41); PolyPhen benign (0.014); catalogued as COSV60242936; called by muse, mutect2, varscan2
- ZNF721 | c.1255A>G p.N419D (on ENST00000338977; = p.N431D on NM_133474.4) | Missense Mutation (SNP) | VAF 7/53 reads (13%) | SIFT tolerated (0.42); PolyPhen probably damaging (0.935); catalogued as COSV59096525; called by muse, mutect2, varscan2
- ZNF761 | c.796G>A p.G266S | Missense Mutation (SNP) | VAF 158/398 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); catalogued as COSV61889391; called by muse, mutect2, varscan2
- ZNF804B | c.1243G>C p.D415H | Missense Mutation (SNP) | VAF 9/105 reads (9%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.707); catalogued as COSV60851068; called by muse, mutect2
- BSN | c.5506G>T p.E1836* | Nonsense Mutation (SNP) | VAF 36/158 reads (23%) | called by muse, mutect2, varscan2
- CEBPB | c.1006G>T p.E336* | Nonsense Mutation (SNP) | VAF 6/14 reads (43%) | called by muse, mutect2
- ELP2 | c.1914G>A p.W638* | Nonsense Mutation (SNP) | VAF 32/66 reads (48%) | called by muse, mutect2, varscan2
- GABRG2 | c.1518C>A p.Y506* (on ENST00000361925 / NM_001375343.1; = p.Y466* on NM_000816.3 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 79/203 reads (39%) | called by muse, mutect2, varscan2
- H2BC10 | c.376A>T p.K126* | Nonsense Mutation (SNP) | VAF 28/60 reads (47%) | called by muse, mutect2, varscan2
- JUNB | c.254C>T p.S85L | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.018); called by muse, mutect2
- KHDC1 | c.385C>T p.Q129* (on ENST00000370384 / NM_001251874.2; = p.Q56* on NM_030568.5) | Nonsense Mutation (SNP) | VAF 12/71 reads (17%) | called by muse, mutect2, varscan2
- KIAA0100 | c.4162C>T p.Q1388* | Nonsense Mutation (SNP) | VAF 26/114 reads (23%) | called by muse, mutect2, varscan2
- NFKBIZ | c.496_507delinsTCCA p.K166Sfs*5 | Frame Shift Del (DEL) | VAF 50/106 reads (47%) | called by pindel, varscan2*
- NXPH1 | c.626T>C p.L209P | Missense Mutation (SNP) | VAF 11/89 reads (12%) | SIFT tolerated (0.2); PolyPhen benign (0.075); called by muse, mutect2
- OTUD4 | c.3133C>T p.Q1045* (on ENST00000447906 / NM_001366057.1; = p.Q980* on NM_001102653.1) | Nonsense Mutation (SNP) | VAF 77/211 reads (36%) | called by muse, mutect2, varscan2
- PPFIA3 | c.2332C>T p.R778* | Nonsense Mutation (SNP) | VAF 47/133 reads (35%) | called by muse, mutect2, varscan2
- PPP4R1 | c.2233C>T p.Q745* (on ENST00000400556 / NM_001042388.3; = p.Q728* on NM_005134.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 33/72 reads (46%) | called by muse, mutect2, varscan2
- TPTE | c.683G>A p.R228K (on ENST00000618007 / NM_199261.4; = p.R210K on NM_199259.4) | Missense Mutation (SNP) | VAF 102/656 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.444); called by muse, mutect2, varscan2
- ACADSB | c.1263G>A p.L421= | Silent (SNP) | VAF 27/123 reads (22%) | catalogued as COSV62551414; called by muse, mutect2, varscan2
- ACVR1C | c.549A>G p.L183= | Silent (SNP) | VAF 62/96 reads (65%) | catalogued as COSV54649402; called by muse, mutect2, varscan2
- ADGRL3 | c.2262G>A p.K754= (on ENST00000506720 / NM_001322402.2; = p.K686= on NM_015236.6) | Silent (SNP) | VAF 17/44 reads (39%) | catalogued as COSV72229483, COSV72231780; called by muse, mutect2, varscan2
- AMFR | c.954G>A p.V318= | Silent (SNP) | VAF 79/189 reads (42%) | catalogued as COSV51923955; called by muse, mutect2, varscan2
- ANKS6 | c.1662G>A p.L554= | Silent (SNP) | VAF 19/65 reads (29%) | catalogued as COSV62049787, COSV62051944; called by muse, mutect2, varscan2
- ATG9A | c.792C>G p.L264= | Silent (SNP) | VAF 17/60 reads (28%) | catalogued as COSV63446673; called by muse, mutect2, varscan2
- AVPR1B | c.858C>T p.I286= | Silent (SNP) | VAF 77/133 reads (58%) | catalogued as rs868923900, COSV65638022; called by muse, mutect2, varscan2
- CDK4 | c.639C>T p.L213= | Silent (SNP) | VAF 14/54 reads (26%) | catalogued as COSV57277064; called by muse, mutect2, varscan2
- CKS1B | c.198C>T p.I66= | Silent (SNP) | VAF 54/58 reads (93%) | catalogued as COSV52699732; called by muse, mutect2, varscan2
- CNOT11 | c.195G>A p.P65= | Silent (SNP) | VAF 8/35 reads (23%) | catalogued as COSV56820925; called by muse, mutect2, varscan2
- CSMD3 | c.198T>A p.G66= | Silent (SNP) | VAF 29/93 reads (31%) | catalogued as rs148820468; called by muse, mutect2, varscan2
- DAAM2 | c.1770C>T p.D590= | Silent (SNP) | VAF 33/74 reads (45%) | catalogued as rs377713628; called by muse, mutect2, varscan2
- DELE1 | c.726C>T p.L242= | Silent (SNP) | VAF 13/38 reads (34%) | catalogued as COSV52006351; called by muse, mutect2, varscan2
- DNER | c.1128C>T p.F376= | Silent (SNP) | VAF 96/174 reads (55%) | catalogued as COSV59160453; called by muse, mutect2, varscan2
- EPHA5 | c.1137G>T p.P379= | Silent (SNP) | VAF 9/58 reads (16%) | catalogued as rs747980985, COSV56654107, COSV56669678; called by muse, mutect2, varscan2
- FAM161A | c.930G>A p.L310= | Silent (SNP) | VAF 64/341 reads (19%) | catalogued as COSV56768458; called by muse, mutect2, varscan2
- FKBP7 | c.186C>A p.G62= | Silent (SNP) | VAF 34/150 reads (23%) | catalogued as COSV51847413; called by muse, mutect2, varscan2
- GLI1 | c.1704C>T p.G568= | Silent (SNP) | VAF 25/137 reads (18%) | catalogued as COSV57366537; called by muse, mutect2, varscan2
- GNMT | c.285A>G p.A95= | Silent (SNP) | VAF 31/86 reads (36%) | catalogued as COSV55105253; called by muse, mutect2, varscan2
- GPR173 | c.420C>T p.C140= | Silent (SNP) | VAF 21/58 reads (36%) | catalogued as rs138728567, COSV60234993; called by muse, mutect2, varscan2
- GRIN2D | c.1647C>T p.I549= | Silent (SNP) | VAF 39/166 reads (23%) | catalogued as COSV54382010; called by muse, mutect2, varscan2
- GTPBP8 | c.210C>T p.I70= | Silent (SNP) | VAF 26/79 reads (33%) | catalogued as COSV55607421, COSV99868430; called by muse, mutect2, varscan2
- HIPK3 | c.2208G>A p.Q736= | Silent (SNP) | VAF 40/138 reads (29%) | catalogued as COSV57565319; called by muse, mutect2, varscan2
- IQCJ | c.390C>T p.L130= | Silent (SNP) | VAF 77/138 reads (56%) | catalogued as COSV67335683; called by muse, mutect2, varscan2
- KCNT2 | c.2811C>T p.I937= | Silent (SNP) | VAF 95/97 reads (98%) | catalogued as rs776647492, COSV54105349; called by muse, mutect2, varscan2
- KRT85 | c.678C>T p.V226= | Silent (SNP) | VAF 64/111 reads (58%) | catalogued as rs766689347, COSV57736644; called by muse, mutect2, varscan2
- LRATD2 | c.300C>G p.G100= | Silent (SNP) | VAF 50/74 reads (68%) | catalogued as COSV59230650; called by muse, mutect2, varscan2
- LY6G6F-LY6G6D | c.486G>A p.G162= | Silent (SNP) | VAF 56/142 reads (39%) | catalogued as COSV65443179; called by muse, mutect2, varscan2
- MELTF | c.285G>A p.V95= | Silent (SNP) | VAF 17/101 reads (17%) | catalogued as COSV56384378; called by muse, mutect2, varscan2
- MMEL1 | c.1188G>A p.Q396= | Silent (SNP) | VAF 22/81 reads (27%) | catalogued as COSV56525729; called by muse, mutect2, varscan2
- MMEL1 | c.1122C>G p.V374= | Silent (SNP) | VAF 23/101 reads (23%) | catalogued as COSV56525745; called by muse, mutect2, varscan2
- MOGAT2 | c.780C>G p.L260= | Silent (SNP) | VAF 90/137 reads (66%) | catalogued as COSV52221240, COSV52221379; called by muse, mutect2, varscan2
- NBEAL2 | c.3405G>A p.L1135= | Silent (SNP) | VAF 5/28 reads (18%) | called by muse, mutect2
- NEK6 | c.941G>A p.*314= | Silent (SNP) | VAF 26/69 reads (38%) | called by muse, mutect2, varscan2
- NOX4 | c.243T>C p.A81= | Silent (SNP) | VAF 13/114 reads (11%) | catalogued as COSV54463279; called by muse, mutect2, varscan2
- NR4A2 | c.1614C>T p.H538= | Silent (SNP) | VAF 30/95 reads (32%) | catalogued as rs550135305, COSV59895453; called by muse, mutect2, varscan2
- OR2T4 | c.1044G>A p.E348= | Silent (SNP) | VAF 163/169 reads (96%) | catalogued as rs745782940, COSV63545057; called by muse, mutect2, varscan2
- PCDHB3 | c.1440A>G p.S480= | Silent (SNP) | VAF 88/202 reads (44%) | catalogued as rs781886254, COSV50584498, COSV99164173; called by muse, mutect2, varscan2
- PINK1 | c.993G>A p.V331= | Silent (SNP) | VAF 25/82 reads (30%) | catalogued as COSV58632774; called by muse, mutect2, varscan2
- PPARG | c.648C>A p.A216= (on ENST00000287820 / NM_015869.5; = p.A186= on NM_005037.7) | Silent (SNP) | VAF 24/153 reads (16%) | catalogued as COSV55143429, COSV55145111; called by muse, mutect2, varscan2
- PRKAB1 | c.111G>A p.L37= | Silent (SNP) | VAF 32/49 reads (65%) | catalogued as COSV57555426; called by muse, mutect2, varscan2
- PRX | c.3033G>A p.G1011= | Silent (SNP) | VAF 75/162 reads (46%) | catalogued as rs1472823467, COSV52532947; called by muse, mutect2, varscan2
- PTPN22 | c.1696C>T p.L566= (on ENST00000359785 / NM_001193431.2; = p.L511= on NM_012411.5) | Silent (SNP) | VAF 80/123 reads (65%) | catalogued as COSV63086399; called by muse, mutect2, varscan2
- RIMBP2 | c.1482C>T p.T494= | Silent (SNP) | VAF 15/26 reads (58%) | catalogued as rs551946345, COSV99898333; called by muse, mutect2, varscan2
- ROCK2 | c.2928G>A p.R976= | Silent (SNP) | VAF 14/49 reads (29%) | catalogued as COSV59964013; called by muse, mutect2, varscan2
- RTN2 | c.936C>A p.P312= | Silent (SNP) | VAF 30/275 reads (11%) | catalogued as COSV55595826; called by muse, mutect2, varscan2
- SLC27A1 | c.1272C>A p.V424= | Silent (SNP) | VAF 30/168 reads (18%) | catalogued as rs912909134, COSV53099585, COSV53100367; called by muse, mutect2, varscan2
- SLC27A1 | c.1401C>G p.V467= | Silent (SNP) | VAF 16/56 reads (29%) | catalogued as COSV53100391; called by muse, mutect2, varscan2
- SMG1 | c.6081C>T p.I2027= | Silent (SNP) | VAF 89/144 reads (62%) | catalogued as COSV67174474; called by muse, mutect2, varscan2
- SNX18 | c.1479C>T p.I493= | Silent (SNP) | VAF 35/94 reads (37%) | catalogued as rs780212988, COSV57991865; called by muse, mutect2, varscan2
- SOWAHB | c.1173C>A p.L391= | Silent (SNP) | VAF 32/153 reads (21%) | catalogued as COSV57555145; called by muse, mutect2, varscan2
- STS | c.297C>T p.F99= | Silent (SNP) | VAF 4/80 reads (5%) | called by muse, mutect2
- TGFB1I1 | c.333C>A p.I111= (on ENST00000394863 / NM_001042454.3; = p.I94= on NM_015927.4) | Silent (SNP) | VAF 33/58 reads (57%) | catalogued as COSV62359092; called by muse, mutect2, varscan2
- TIMELESS | c.1605G>A p.K535= | Silent (SNP) | VAF 67/103 reads (65%) | catalogued as rs761880221, COSV57514788; called by muse, mutect2, varscan2
- TMEM38A | c.234C>T p.I78= | Silent (SNP) | VAF 48/130 reads (37%) | catalogued as rs144587502; called by muse, mutect2, varscan2
- TNRC6A | c.3057G>A p.V1019= | Silent (SNP) | VAF 12/108 reads (11%) | catalogued as COSV59369463; called by muse, mutect2, varscan2
- TSHZ3 | c.2667G>A p.Q889= | Silent (SNP) | VAF 56/111 reads (50%) | catalogued as COSV53680978; called by muse, mutect2, varscan2
- TTC23 | c.1011G>A p.L337= | Silent (SNP) | VAF 61/102 reads (60%) | catalogued as COSV50444047; called by muse, mutect2, varscan2
- VPS13B | c.3192G>A p.V1064= | Silent (SNP) | VAF 18/73 reads (25%) | catalogued as COSV62155036; called by muse, mutect2, varscan2
- ZC3H10 | c.781C>T p.L261= | Silent (SNP) | VAF 39/123 reads (32%) | catalogued as COSV57769876; called by muse, mutect2, varscan2
- ZFHX4 | c.4375C>T p.L1459= | Silent (SNP) | VAF 14/55 reads (25%) | catalogued as COSV51492494; called by muse, mutect2, varscan2
- ZNF512 | c.753C>G p.L251= | Silent (SNP) | VAF 9/66 reads (14%) | catalogued as COSV62677999; called by muse, mutect2, varscan2
- ZNF710 | c.1722C>T p.P574= | Silent (SNP) | VAF 50/81 reads (62%) | catalogued as COSV51565344; called by muse, mutect2, varscan2
- ZNF878 | c.1485C>T p.L495= | Silent (SNP) | VAF 22/63 reads (35%) | catalogued as COSV72156107; called by muse, mutect2, varscan2
- AC245047.1 | n.18G>A | RNA (SNP) | VAF 140/150 reads (93%) | called by muse, mutect2, varscan2
- AP000769.3 | chr11:65501260 C>T | 5'Flank (SNP) | VAF 13/43 reads (30%) | catalogued as rs367741529; called by muse, mutect2, varscan2
- AP000769.3 | chr11:65501700 C>T | 5'Flank (SNP) | VAF 26/75 reads (35%) | catalogued as rs759658970; called by muse, mutect2, varscan2
- AP000769.3 | chr11:65503987 G>C | 5'Flank (SNP) | VAF 7/23 reads (30%) | called by muse, mutect2, varscan2
- AP000769.3 | chr11:65504230 G>A | 5'Flank (SNP) | VAF 10/34 reads (29%) | called by muse, mutect2, varscan2
- AP000769.3 | chr11:65504927 G>A | 5'Flank (SNP) | VAF 7/33 reads (21%) | called by muse, varscan2
- AP000769.3 | chr11:65505208 G>A | 5'Flank (SNP) | VAF 24/74 reads (32%) | catalogued as rs370181065; called by muse, mutect2, varscan2
- AP000769.3 | chr11:65505361 G>A | 5'Flank (SNP) | VAF 21/65 reads (32%) | catalogued as rs756975149; called by muse, mutect2, varscan2
- AP000769.5 | chr11:65498825 C>G | 5'Flank (SNP) | VAF 48/186 reads (26%) | catalogued as rs769998483; called by muse, mutect2, varscan2
- AP000769.5 | chr11:65500454 C>A | 5'Flank (SNP) | VAF 22/77 reads (29%) | called by muse, mutect2, varscan2
- CPLANE1 | c.*3791G>C | 3'UTR (SNP) | VAF 20/75 reads (27%) | catalogued as COSV57072395; called by muse, mutect2, varscan2
- KIF1B | c.2115+6792C>G | Intron (SNP) | VAF 115/185 reads (62%) | catalogued as COSV55814165, COSV99822983; called by muse, mutect2, varscan2
- PIGF | c.546+4327G>C | Intron (SNP) | VAF 15/79 reads (19%) | catalogued as COSV55590153; called by muse, mutect2, varscan2
